CPTAC case C3L-01838 — Bronchus and lung — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/006931bb-f5b1-4aa4-b0a8-af517a912db0

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1947; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lung, NOS; Age at diagnosis: 70.3 years (25,663 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T2a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IB; Tumor grade: G2; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 1,707 days (4.7 years); Progression or recurrence: no; Days to last follow up: 1,707 days (4.7 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 4 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 0; Margin status: Uninvolved.

Follow-up (6 entries)
- Days to follow up: 332 days; Disease response: Tumor Free.
- Days to follow up: 699 days (1.9 years); Disease response: Tumor Free.
- Days to follow up: 1,029 days (2.8 years); Disease response: Tumor Free.
- Days to follow up: 1,382 days (3.8 years); Disease response: Tumor Free.
- Days to follow up: 1,382 days (3.8 years); Disease response: Complete Response.
- Days to follow up: 1,707 days (4.7 years); Disease response: Tumor Free.

Other clinical attributes
- Weight: 81 kg; Height: 170 cm; BMI: 28.03; DLCO (% of predicted): 71; FEV1/FVC after bronchodilator (%): 59; FEV1/FVC before bronchodilator (%): 55; FEV1 after bronchodilator (% of reference): 72; FEV1 before bronchodilator (% of reference): 66.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 33; Cigarettes per day: 20; Tobacco smoking onset year: 1965; Tobacco smoking quit year: 1998; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 33.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-01838-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 308 mg; Time between excision and freezing: 17 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-01838-23: Section location: Right upper and middle lobe; Percent tumor nuclei: 60; Percent necrosis: 15.
- Sample C3L-01838-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 396 mg.
- Sample C3L-01838-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
